CTSP case CTSP-ACYS — CTSP-DLBCL1: CTSP Diffuse Large B-Cell Lymphoma (DLBCL) CALGB 50303
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ad38dc02-4775-49f9-bede-79e10cc2c5e7

Demographics
Sex at birth: female; Race: white; Year of birth: 1958; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Age at diagnosis: 48.7 years (17,778 days); Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage IV; Days to last follow up: 3,676 days (10.1 years); Best overall response: Partial Response; Ann Arbor extranodal involvement: Yes; Double expressor lymphoma: No; Double hit lymphoma: No; International Prognostic Index (IPI): High-Intermediate Risk.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 79 kg; Height: 161 cm; BMI: 30.5.

Biospecimens (1 sample)
- Sample DLBCL11292-sample: Sample type: Tumor; Tissue type: Tumor.
